CCDI case PBCJFD — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS.
https://portal.gdc.cancer.gov/cases/2efc7dd5-718d-4617-9249-d24b66fd52a3

Demographics
Sex at birth: male; Race: asian.

Diagnoses (1)
1. Undifferentiated sarcoma: ICD-O-3 morphology code: 8805/3; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 3.1 years (1,118 days).

Biospecimens (3 samples)
- Samples 0DT9MT, 0DT9NO (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DT9NB: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
